Gene-level copy-number profile of tumor specimen RC-B6VM-TBP1-A from RC case RC-B6VM, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 58.9 years (21,510 days).
Specimen RC-B6VM-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c53a71c-0311-4d36-9249-bdd1459db8e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6VM-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/59a77460-7c79-4f9a-8d02-5a03e77b262b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 310; copy number 2: 58,058; copy number 3: 16.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–2): TRGC1.
- chr7:38,276,259–38,329,643, 8 genes (within-gene range 0–2): TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr12:133,238,335–133,238,549, 2 genes: RNU6-717P, Y_RNA.
- chr14:22,415,362–22,469,698, 11 genes (within-gene range 0–2): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 309. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
